Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A46I, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A46I-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3 + 4 = 7.
- B. CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT SIDES OF PROSTATE AND HAS A GREATEST NODULAR DIAMETER OF 2.3 CM IN ONE HISTOLOGIC SECTION.
- C. CARCINOMA INVOLVES APPROXIMATELY 15% OF THE EXAMINED PROSTATE BY VOLUME.
- D. THE TUMOR SHOWS FOCAL EXTRAPROSTATIC EXTENSION AT THE LEFT ANTERIOR APEX (BLOCK 1P).
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. MULTIFOCAL PERINEURAL INVASION IS PRESENT.
- H. ANGIOLYMPHATIC INVASION IS NOT IDENTIFIED.
- I. MULTIFOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS PRESENT.
- J. PATHOLOGIC TNM STAGE: pT3a Nx.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA: PSA value: 8.48
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
PRIMARY GLEASON GRADE: 3
SECONDARY GLEASON GRADE: 4
GLEASON SUM SCORE: 7
GLEASON 4/5 PERCENTAGE: 45%
WEIGHT OF PROSTATE: 45.85gm
TUMOR SIZE: Maximum dimension: 2.3 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: 5 - 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - multifocal
EXTRAPROSTATIC EXTENSION: Yes - Focal
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
RESIDUAL TUMOR: R0
LYMPH NODES EXAMINED: 0
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT3a
N STAGE, PATHOLOGIC: pNX
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

1c5-0-3
adenocarcinoma, acinar 8550/3
Site: prostate, NOS <61.9
7/27/12

Source: NCI Genomic Data Commons file 4faccb3d-bef6-4693-a6bf-4420d0c218c9 (TCGA-EJ-A46I.741CC282-0593-45E4-BEEB-343339F891AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).